Gene-level copy-number profile of tumor specimen TCGA-2G-AAG9-01A from TCGA case TCGA-2G-AAG9, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 25.2 years (9,210 days).
Specimen TCGA-2G-AAG9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-TGCT.f7a7b62b-4e80-4bc4-9b1c-a00676cae155.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2G-AAG9-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fec0b2c2-7b24-4a9e-8168-63804cbde453

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 470; copy number 2: 21,764; copy number 3: 28,583; copy number 4: 7,467; copy number 5: 184; copy number 6: 278; copy number 7: 219; copy number 9: 850.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2G-AAG9-01A-11D-A42X-01): tumor purity 0.55, ploidy 2.82, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,069 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:46,549,089–60,664,530, 219 genes, copy number 7 (broad region; genes not listed).
- chr12:66,767–34,249,958, 850 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 470. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
